Somatic mutation profile of tumor specimen MP2PRT-PATZIX-TMP1-A (aliquot MP2PRT-PATZIX-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PATZIX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,734 days).
Specimen MP2PRT-PATZIX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c9ed7cf-663c-45ad-a3f8-bbb6396a9b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZIX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZIX-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef009205-356e-48cb-a06d-92e4f69072ad

The open-access MAF lists 130 somatic variants for this specimen: 81 protein-altering or splice-affecting, 46 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 46, Nonsense Mutation 4, Intron 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 106/360 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 85/347 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs397507539, CM044253, CM122802, CX097234, COSV61006286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.1586G>T p.C529F | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57007646; called by muse, mutect2, varscan2
- AQP1 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV61266388, COSV61268699; called by muse, mutect2, varscan2
- ARHGAP36 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 165/568 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs866987298, COSV99357740; called by muse, mutect2, varscan2
- BOD1L2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 129/399 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as rs772124087; called by muse, mutect2, varscan2
- CD3E | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs1472836910, COSV62345843; called by muse, mutect2, varscan2
- CFAP43 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV53376852; called by muse, mutect2, varscan2
- CFAP61 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.23); catalogued as rs750064612, COSV55633991; called by muse, mutect2, varscan2
- CFHR1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs753093577, COSV57626056; called by muse, mutect2, varscan2
- CHRNA7 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772533362; called by muse, mutect2, varscan2
- CPNE8 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 122/319 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1481031948, COSV58850329; called by muse, mutect2, varscan2
- DAAM2 | c.2776G>A p.E926K (on ENST00000274867 / NM_001201427.2; = p.E925K on NM_015345.3) | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs755546323; called by muse, varscan2
- DGAT2L6 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs762343876, COSV60718774; called by muse, mutect2, varscan2
- DLC1 | c.3875G>A p.R1292Q (on ENST00000276297 / NM_001348081.2; = p.R855Q on NM_006094.5) | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200504821; called by muse, mutect2, varscan2
- DNAH11 | c.8854C>T p.H2952Y | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV100179509; called by muse, mutect2, varscan2
- DSCAM | c.5930C>A p.A1977E | Missense Mutation (SNP) | VAF 64/890 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1445906235; called by muse, mutect2
- FAT1 | c.11542G>A p.E3848K | Missense Mutation (SNP) | VAF 58/644 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.872); catalogued as COSV71673301; called by muse, mutect2
- FREM1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs772215299, COSV101085775, COSV66518648; called by muse, mutect2, varscan2
- KIF21A | c.2298G>A p.M766I (on ENST00000361418 / NM_001378440.1; = p.M753I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1259861197; called by muse, mutect2
- KIF21B | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59757890; called by muse, mutect2, varscan2
- LAMA2 | c.3294G>A p.W1098* | Nonsense Mutation (SNP) | VAF 117/570 reads (21%) | catalogued as rs1298336252, CD102058, COSV70340654, COSV70355786; called by muse, mutect2, varscan2
- LAMA4 | c.3664G>A p.G1222R (on ENST00000230538 / NM_001105206.3; = p.G1215R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/447 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782523789; called by muse, mutect2, varscan2
- LIN7A | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54021762; called by muse, mutect2, varscan2
- LNX1 | c.1018G>A p.A340T (on ENST00000263925 / NM_001126328.3; = p.A244T on NM_032622.2) | Missense Mutation (SNP) | VAF 90/484 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761909300, COSV99820888; called by muse, mutect2, varscan2
- LRIT1 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 133/442 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs138374131; called by muse, mutect2, varscan2
- MPL | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 57/468 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as rs6088, COSV65244000; called by muse, mutect2, varscan2
- NUMA1 | c.4132G>A p.E1378K | Missense Mutation (SNP) | VAF 61/434 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1429266454; called by muse, mutect2, varscan2
- OCA2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 49/368 reads (13%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV62339231; called by muse, mutect2, varscan2
- OR4A8 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 102/280 reads (36%) | catalogued as rs182945238; called by muse, mutect2, varscan2
- OR5R1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 107/430 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs368362913, COSV56572291; called by muse, mutect2
- OR6C68 | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 93/294 reads (32%) | catalogued as rs764488152; called by muse, mutect2, varscan2
- PAPPA | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs142893148, COSV60294044; called by muse, mutect2, varscan2
- PGAP1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61326071; called by muse, varscan2
- PPEF2 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 70/366 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV99714004; called by muse, mutect2, varscan2
- RHAG | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 86/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57704704, COSV57706532; called by muse, mutect2, varscan2
- SH3BP4 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373202308; called by muse, mutect2
- SPIRE2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 198/578 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs536297560; called by muse, varscan2
- STXBP5 | c.2066G>T p.R689L | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV99471230; called by muse, mutect2
- SYNPR | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 109/345 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs756375711; called by muse, varscan2
- UBN2 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 139/466 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs1291076938; called by muse, mutect2, varscan2
- ZC3H15 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs772217905; called by muse, mutect2, varscan2
- ACP3 | c.969G>A p.G323= | Splice Region (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- ADAM29 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 102/504 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP8A2 | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 108/385 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRSK2 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- CHD3 | c.5899C>T p.P1967S (on ENST00000330494 / NM_001005273.3; = p.P1933S on NM_005852.4) | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- CHD3 | c.5900C>T p.P1967L (on ENST00000330494 / NM_001005273.3; = p.P1933L on NM_005852.4) | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2
- CRELD1 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 147/460 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- DAP3 | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ELANE | c.-4_19delinsGCTT | Translation Start Site (DEL) | VAF 154/497 reads (31%) | called by pindel, varscan2*
- FAM169A | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FER1L5 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 99/405 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 65/493 reads (13%) | called by muse, mutect2, varscan2
- HOXD12 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 135/429 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- IQCM | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 113/600 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KIF6 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 57/669 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2
- LCA5 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 46/666 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.033); called by muse, mutect2
- LRRC9 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MAGEA1 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MUC12 | c.8971C>G p.P2991A (on ENST00000379442; = p.P2848A on NM_001164462.1) | Missense Mutation (SNP) | VAF 62/1314 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); called by muse, mutect2
- NDST3 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- NPY2R | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 108/601 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OCA2 | c.225G>A p.G75= | Splice Region (SNP) | VAF 49/363 reads (13%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.1424C>T p.S475F (on ENST00000283426; = p.S831F on NM_052909.5) | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POPDC3 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 95/491 reads (19%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- RAPGEF5 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 144/437 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- REG1A | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- SCD | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 146/428 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SCN3A | c.3003G>A p.M1001I | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SETD2 | c.4095_4099dup p.V1367Gfs*8 | Frame Shift Ins (INS) | VAF 44/361 reads (12%) | called by mutect2, pindel, varscan2
- SH2B1 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 148/359 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC25A44 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A9 | c.77T>C p.L26S | Missense Mutation (SNP) | VAF 49/402 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC6A20 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SMARCD1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TMEM101 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 145/427 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, varscan2
- TPSD1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 165/666 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, varscan2
- TSHB | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2
- UBN2 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 142/468 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VIPAS39 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 58/538 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- ADGRG4 | c.9057G>A p.Q3019= | Silent (SNP) | VAF 85/282 reads (30%) | called by muse, mutect2, varscan2
- ANXA5 | c.585C>T p.I195= | Silent (SNP) | VAF 64/376 reads (17%) | catalogued as rs1560824001, COSV56639417; called by muse, mutect2, varscan2
- ATP7B | c.2959C>T p.L987= | Silent (SNP) | VAF 140/462 reads (30%) | called by muse, mutect2, varscan2
- ATP7B | c.2958C>T p.S986= | Silent (SNP) | VAF 137/457 reads (30%) | catalogued as COSV54440467; called by muse, mutect2, varscan2
- BACE2 | c.1230G>A p.T410= | Silent (SNP) | VAF 111/731 reads (15%) | catalogued as rs199826508; called by muse, mutect2, varscan2
- CCDC183 | c.48G>A p.L16= | Silent (SNP) | VAF 89/295 reads (30%) | called by muse, mutect2, varscan2
- CD209 | c.834C>T p.H278= | Silent (SNP) | VAF 89/350 reads (25%) | catalogued as rs61742035, COSV52654363; called by muse, mutect2, varscan2
- COL6A2 | c.3030C>T p.F1010= | Silent (SNP) | VAF 94/613 reads (15%) | catalogued as COSV52428384; called by muse, mutect2
- CRACD | c.1170G>A p.G390= | Silent (SNP) | VAF 178/789 reads (23%) | catalogued as rs748869826; called by muse, mutect2, varscan2
- CRACD | c.1710C>T p.P570= | Silent (SNP) | VAF 50/742 reads (7%) | called by muse, mutect2
- DOCK5 | c.2826G>A p.G942= | Silent (SNP) | VAF 28/310 reads (9%) | catalogued as rs1292245393; called by muse, mutect2
- EGFR | c.738C>T p.S246= | Silent (SNP) | VAF 51/359 reads (14%) | catalogued as rs772130986, COSV51781280, COSV51815394; called by muse, mutect2, varscan2
- ENPP7 | c.579C>T p.L193= | Silent (SNP) | VAF 137/447 reads (31%) | catalogued as rs782005485; called by muse, mutect2, varscan2
- F10 | c.1353C>T p.I451= | Silent (SNP) | VAF 62/431 reads (14%) | called by muse, mutect2, varscan2
- FAM133A | c.513G>A p.K171= | Silent (SNP) | VAF 31/292 reads (11%) | called by muse, mutect2, varscan2
- FAM214B | c.1224C>T p.I408= | Silent (SNP) | VAF 86/268 reads (32%) | catalogued as rs140820493; called by muse, varscan2
- GABRB1 | c.45C>T p.F15= | Silent (SNP) | VAF 56/592 reads (9%) | catalogued as COSV54972831; called by muse, mutect2
- GFER | c.30C>T p.F10= | Silent (SNP) | VAF 109/376 reads (29%) | called by muse, mutect2, varscan2
- GFRAL | c.1099C>T p.L367= | Silent (SNP) | VAF 39/420 reads (9%) | catalogued as COSV61235693; called by muse, mutect2
- GGA1 | c.1353C>T p.P451= | Silent (SNP) | VAF 89/375 reads (24%) | called by muse, mutect2, varscan2
- GYG2 | c.780G>A p.Q260= | Silent (SNP) | VAF 134/441 reads (30%) | called by muse, mutect2, varscan2
- KIF25 | c.801C>T p.L267= | Silent (SNP) | VAF 54/657 reads (8%) | catalogued as rs751690533; called by muse, mutect2
- KIR2DL3 | c.15C>T p.V5= | Silent (SNP) | VAF 46/384 reads (12%) | catalogued as rs748497705, COSV52545491, COSV99400171; called by muse, mutect2, varscan2
- LYZL2 | c.582C>T p.S194= (on ENST00000375318; = p.S148= on NM_183058.3) | Silent (SNP) | VAF 65/250 reads (26%) | called by muse, mutect2, varscan2
- MAST1 | c.1740C>T p.F580= | Silent (SNP) | VAF 49/448 reads (11%) | catalogued as COSV52241643; called by muse, mutect2, varscan2
- MINAR1 | c.2133C>T p.S711= | Silent (SNP) | VAF 44/376 reads (12%) | called by muse, mutect2, varscan2
- MYO15A | c.1518C>T p.P506= | Silent (SNP) | VAF 43/361 reads (12%) | catalogued as rs556943201, COSV99232870; called by muse, mutect2, varscan2
- NRXN1 | c.663G>A p.E221= | Silent (SNP) | VAF 181/596 reads (30%) | catalogued as rs201356864; called by muse, mutect2, varscan2
- OGFOD3 | c.840C>T p.F280= | Silent (SNP) | VAF 44/329 reads (13%) | called by muse, mutect2, varscan2
- OSBPL5 | c.2475C>T p.I825= | Silent (SNP) | VAF 54/390 reads (14%) | called by muse, mutect2, varscan2
- OTUD6A | c.855G>A p.P285= | Silent (SNP) | VAF 118/365 reads (32%) | catalogued as rs748580751; called by muse, mutect2, varscan2
- PAK4 | c.744G>A p.R248= | Silent (SNP) | VAF 64/431 reads (15%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.1390C>T p.L464= | Silent (SNP) | VAF 148/441 reads (34%) | catalogued as COSV53848700; called by muse, mutect2, varscan2
- PCSK5 | c.900G>A p.R300= | Silent (SNP) | VAF 73/279 reads (26%) | called by muse, mutect2, varscan2
- PMP22 | c.210C>T p.I70= | Silent (SNP) | VAF 43/346 reads (12%) | catalogued as rs759343506; called by muse, mutect2, varscan2
- PRSS12 | c.1089C>T p.S363= | Silent (SNP) | VAF 48/687 reads (7%) | catalogued as rs756346330, COSV56604601; called by muse, mutect2
- SLC8A2 | c.1653G>A p.A551= | Silent (SNP) | VAF 84/593 reads (14%) | catalogued as rs1299208514; called by muse, mutect2, varscan2
- SMLR1 | c.177C>T p.F59= | Silent (SNP) | VAF 75/392 reads (19%) | catalogued as rs1253966746; called by muse, mutect2, varscan2
- TGFBR3 | c.2400C>T p.L800= | Silent (SNP) | VAF 38/280 reads (14%) | catalogued as rs1557661378; called by muse, mutect2, varscan2
- TGM4 | c.939G>A p.E313= | Silent (SNP) | VAF 45/294 reads (15%) | catalogued as COSV56093322; called by muse, mutect2, varscan2
- TRIM63 | c.450C>T p.I150= | Silent (SNP) | VAF 45/406 reads (11%) | called by muse, mutect2, varscan2
- UBTD1 | c.651C>T p.V217= | Silent (SNP) | VAF 54/313 reads (17%) | called by muse, mutect2, varscan2
- ULBP1 | c.27C>T p.F9= | Silent (SNP) | VAF 132/627 reads (21%) | called by muse, mutect2, varscan2
- ZBTB7A | c.1002G>A p.A334= | Silent (SNP) | VAF 70/561 reads (12%) | catalogued as rs1173121935; called by muse, mutect2, varscan2
- ZFHX4 | c.5502G>A p.L1834= | Silent (SNP) | VAF 67/480 reads (14%) | called by muse, mutect2, varscan2
- ZNF648 | c.981C>T p.R327= | Silent (SNP) | VAF 85/546 reads (16%) | called by muse, mutect2, varscan2
- NPDC1 | c.113-161C>T | Intron (SNP) | VAF 50/324 reads (15%) | called by muse, mutect2, varscan2
- PAX7 | c.1402+57G>A | Intron (SNP) | VAF 46/472 reads (10%) | catalogued as rs1370919716; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22612276 G>A | 5'Flank (SNP) | VAF 30/231 reads (13%) | catalogued as rs1351346595; called by muse, mutect2, varscan2
